Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2X, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2X-01A (Primary Tumor).

[page 1 of 2]
Male

Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

SLIDE DISPOSITION:

DIAGNOSIS:

A. Lymph node, liver hilum, biopsy: A single (1) lymph node is negative for tumor.

B. Common bile duct, distal margin, excision: Negative for tumor.

C. Liver, left lobe and gallbladder, partial hepatectomy and cholecystectomy: Invasive Grade 4 (of 4) adenocarcinoma with mucinous and signet ring cell features, is identified forming a mass (2.9 x 2.6 x 2.0 cm) involving the left hepatic duct. The tumor directly invades the adjacent liver parenchyma. The hepatic parenchymal resection margin is involved by invasive carcinoma. Lymphovascular invasion is identified. Perineural invasion is not identified. The gall bladder is uninvolved and shows chronic cholecystitis. The non-neoplastic hepatic parenchyma will be reviewed on permanent sections with special stains and reported in an addendum.

D. Right main bile duct, margin, excision: Negative for tumor.

E. Liver, caudate lobe, partial hepatectomy: Negative for tumor.

F. Lymph nodes, hepatic duodenal, biopsy: Metastatic grade 4 (of 4) adenocarcinoma is identified in a single (1 of 3) lymph node.

With available surgical material, [AJCC pT2bN1] (7th edition, 2010).

Frozen section histologic interpretation of liver hilum lymph node, common bile duct margin, and right main bile duct margin performed by:

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ADDENDUM:

Non-neoplastic liver parenchyma showing portal tract expansion by mild chronic inflammation, edema and bile ductule proliferation, consistent with bile flow obstruction. There is mild macrovesicular steatosis and mild cholestasis. The trichrome shows mild portal fibrosis. Iron stain is negative. PAS-D stain is negative for intracytoplasmic globules.

GROSS DESCRIPTION:

A. Received fresh labeled "lymph node; liver hilum, biopsy" is a 2.0 x 1.3 x 0.6 cm lymph node. All submitted. Grossed by

B. Received fresh labeled "distal common bile duct margin - margin

ICD O-5
Cholangiocarcinoma 8160/3

with Adenocarcinoma, mucinous +
signet ring cell (8490/3) Code to highest 8490/3
Site: Hepatic duct C24.0
7/23/14

[page 2 of 2]
up" is a 1.1 x 0.6 x 0.6 cm portion of pink-tan tissue with orientation. Margin submitted. Grossed by

C. Received fresh labeled "left hepatectomy" is a 525 gram, 22.5 x 13.0 x 5.2 cm liver wedge specimen with an 8.0 x 3.0 x 1.5 cm gallbladder and a 13.9 cm stent. A single 2.9 x 2.6 x 2.0 cm tan-white mass is present at the inked surgical margin. The mass underlies the left hepatic duct but does not grossly appear to involve the duct lumen. Surgical resection margin is submitted perpendicularly. The common bile duct margin is widely free of tumor. The gallbladder has a wall thickness of 0.2 cm. No stones are present. No cholesterosis. Representative sections are submitted. Grossed by

D. Received fresh labeled "right main bile duct - margin up" is a 1.5 x 1.0 x 0.3 cm portion of tan-pink bile duct with orientation. All submitted. Grossed by

E. Received fresh labeled "caudate lobe of liver" is a 7.7 x 5.3 x 3.4 cm portion of liver. There is a 0.2 x 0.2 cm pale tan thickening on the caudate capsule. No masses are identified. Representative sections are submitted. Grossed by

F. Received fresh labeled "hepatic duodenal lymph nodes" are three lymph nodes measuring 2.2 x 1.3 x 1.3 cm, 2.2 x 1.1 x 1.0 cm, and 1.7 x 0.6 x 0.5 cm. A single lymph node is grossly positive with a metastasis measuring 1.3 x 1.1 x 1.0 cm. Lymph nodes submitted. Grossed by

Source: NCI Genomic Data Commons file f5aef9bf-2485-4f5f-af4e-76ecadb4ca4a (TCGA-W5-AA2X.D2B18607-E16D-4570-9E96-5A7CBAFD79FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).